Somatic mutation profile of tumor specimen TCGA-FD-A3SL-01A (aliquot TCGA-FD-A3SL-01A-21D-A22Z-08) from TCGA case TCGA-FD-A3SL, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 60.3 years (22,020 days).
Specimen TCGA-FD-A3SL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d1c25c99-440b-48fc-855f-d9b5c206ca30.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FD-A3SL-10A (Blood Derived Normal), aliquot TCGA-FD-A3SL-10A-01D-A22Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ac55291-2378-443c-aa59-db53d34d842f

The open-access MAF lists 245 somatic variants for this specimen: 184 protein-altering or splice-affecting, 55 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 155, Silent 55, Nonsense Mutation 11, Frame Shift Del 7, Splice Site 5, Intron 4, Frame Shift Ins 3, Nonstop Mutation 2, 5'UTR 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4303G>C p.D1435H | Missense Mutation (SNP) | VAF 12/32 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52114189, COSV52125802, COSV52127728; called by muse, mutect2, varscan2
- ABCC11 | c.1538C>T p.A513V | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.093); catalogued as COSV62323898; called by muse, mutect2, varscan2
- ABL2 | c.2800C>T p.L934F (on ENST00000502732 / NM_007314.4; = p.L919F on NM_005158.5) | Missense Mutation (SNP) | VAF 69/132 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as COSV61016312; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1097G>C p.G366A | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV55001309; called by muse, mutect2, varscan2
- ADRA1D | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1192475463, COSV65241196; called by muse, mutect2, varscan2
- AHCYL2 | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.554); catalogued as COSV61488159; called by muse, mutect2, varscan2
- AKAP11 | c.4340A>G p.Y1447C | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV50297767; called by muse, mutect2, varscan2
- ANKRD29 | c.196G>A p.V66I | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0.011); catalogued as COSV52426410; called by muse, mutect2, varscan2
- ANKZF1 | c.827G>C p.R276P | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV55477067; called by muse, mutect2, varscan2
- ARF3 | c.148+1G>C p.X50_splice | Splice Site (SNP) | VAF 57/128 reads (45%) | catalogued as rs756541213, COSV56741442; called by muse, mutect2, varscan2
- ARHGAP28 | c.1697T>A p.I566N (on ENST00000383472 / NM_001366230.1; = p.I407N on NM_001010000.3) | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV51639898; called by muse, mutect2, varscan2
- ARHGEF37 | c.1908C>A p.D636E | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61369068; called by muse, mutect2, varscan2
- ATG4C | c.715C>G p.H239D | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58606435; called by muse, mutect2, varscan2
- ATP2B1 | c.1815G>C p.E605D | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53809008; called by muse, mutect2, varscan2
- ATXN2 | c.1855+1G>A p.X619_splice (on ENST00000550104; = p.X459_splice on NM_002973.4) | Splice Site (SNP) | VAF 7/35 reads (20%) | catalogued as COSV66483908; called by muse, mutect2, varscan2
- AUP1 | c.752A>G p.E251G | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV51208912; called by muse, mutect2, varscan2
- B3GNT8 | c.503G>C p.R168T | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV54196306, COSV54197815; called by muse, mutect2, varscan2
- BRSK1 | c.1096G>A p.D366N | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV58664887; called by muse, mutect2, varscan2
- C11orf45 | c.156G>T p.R52S | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.094); catalogued as COSV57967186; called by muse, mutect2, varscan2
- C1orf146 | c.349C>G p.R117G | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV64860753; called by muse, mutect2, varscan2
- C21orf58 | c.791A>C p.K264T | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as COSV52450235; called by muse, mutect2, varscan2
- C5orf51 | c.707A>G p.D236G | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV67565978; called by muse, mutect2, varscan2
- CACNA1H | c.677C>T p.T226M | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770952533, COSV61993743; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCT5 | c.173A>T p.D58V | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54724425; called by muse, mutect2, varscan2
- CDH16 | c.1931C>G p.P644R | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.751); catalogued as COSV55337257; called by muse, mutect2, varscan2
- CDK15 | c.528C>G p.F176L (on ENST00000652192 / NM_001366386.2; = p.F125L on NM_139158.2) | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT tolerated (0.89); PolyPhen benign (0.174); catalogued as COSV53635436, COSV53639513; called by muse, mutect2, varscan2
- CHRNE | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 63/176 reads (36%) | SIFT tolerated (0.91); PolyPhen benign (0.035); catalogued as COSV53418506; called by muse, mutect2, varscan2
- CHRNG | c.1139G>T p.G380V | Missense Mutation (SNP) | VAF 57/128 reads (45%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV67315672; called by muse, mutect2, varscan2
- CHST8 | c.50T>A p.I17N | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV52859865; called by muse, mutect2, varscan2
- COCH | c.1321A>T p.S441C (on ENST00000216361 / NM_001347720.1; = p.S376C on NM_004086.3) | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53551414; called by muse, mutect2, varscan2
- COL6A6 | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.108); catalogued as rs760464848, COSV100650493, COSV62028111; called by muse, mutect2, varscan2
- COLGALT2 | c.1700G>A p.G567E | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT tolerated (0.27); PolyPhen probably damaging (1); catalogued as COSV62299720; called by muse, mutect2, varscan2
- COMMD1 | c.341G>T p.R114L | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.599); catalogued as COSV61277288; called by muse, mutect2, varscan2
- COMT | c.452G>C p.R151P | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.485); catalogued as COSV52890125; called by muse, varscan2
- CORO1A | c.444_445insT p.S149* | Frame Shift Ins (INS) | VAF 10/48 reads (21%) | catalogued as COSV54631407; called by mutect2, pindel*, varscan2
- CREBL2 | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57428438; called by muse, mutect2, varscan2
- DCAF6 | c.128T>G p.L43R | Missense Mutation (SNP) | VAF 59/94 reads (63%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV56580134; called by muse, mutect2, varscan2
- DDAH1 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as COSV52304624; called by muse, mutect2, varscan2
- DIS3L2 | c.1130A>G p.D377G | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV56056797; called by muse, mutect2, varscan2
- DST | c.10228G>T p.D3410Y | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV55021399; called by muse, mutect2, varscan2
- DUSP2 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as COSV56619683; called by muse, mutect2, varscan2
- EBF3 | c.334C>G p.L112V | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.161); catalogued as rs1273663956, COSV62476428; called by muse, mutect2, varscan2
- ETFDH | c.7G>T p.V3L | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as COSV57015281; called by muse, mutect2, varscan2
- FAM219A | c.464A>G p.D155G (on ENST00000445726; = p.D138G on NM_147202.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52621247; called by muse, mutect2, varscan2
- FBXL20 | c.888+2T>A p.X296_splice | Splice Site (SNP) | VAF 20/38 reads (53%) | catalogued as COSV52900189; called by muse, mutect2, varscan2
- FOXC1 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.381); catalogued as COSV66516676; called by muse, mutect2
- FREM1 | c.2486G>C p.G829A | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.53); catalogued as rs373420008; called by muse, mutect2, varscan2
- GAB2 | c.143A>G p.Y48C (on ENST00000361507 / NM_080491.3; = p.Y10C on NM_012296.3) | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779373428, COSV60868713; called by muse, mutect2, varscan2
- GABRA6 | c.1360T>A p.*454Kext*7 | Nonstop Mutation (SNP) | VAF 15/87 reads (17%) | catalogued as rs201411758; called by muse, mutect2, varscan2
- GALNT15 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs372125358, COSV60216262; called by muse, mutect2, varscan2
- GCC2 | c.3060G>C p.K1020N | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV59177216; called by muse, mutect2, varscan2
- GKAP1 | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.082); catalogued as COSV64489186; called by muse, mutect2, varscan2
- GMPPA | c.481A>C p.T161P | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV58007290; called by muse, mutect2, varscan2
- GNB4 | c.640C>G p.R214G | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV51710033, COSV51710386, COSV99224444; called by muse, mutect2, varscan2
- GRIK4 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs138617238; called by muse, mutect2, varscan2
- GRM5 | c.1735G>A p.E579K | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV100552709, COSV59610323; called by muse, mutect2, varscan2
- HEATR1 | c.135C>A p.F45L | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.37); catalogued as COSV63979429, COSV63979467; called by muse, mutect2
- HERC1 | c.6965G>C p.R2322P | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.854); catalogued as rs374367917, COSV71248422; called by muse, mutect2, varscan2
- HIPK1 | c.491C>T p.T164I | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as COSV65785402; called by muse, mutect2, varscan2
- HS2ST1 | c.634G>C p.E212Q | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as COSV63351043; called by muse, mutect2, varscan2
- KANSL1 | c.910C>G p.R304G | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52269926, COSV99294093; called by muse, mutect2, varscan2
- KHDRBS3 | c.870C>A p.S290R | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.678); catalogued as COSV63420147; called by muse, mutect2, varscan2
- KLHL15 | c.554A>G p.D185G | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.098); catalogued as COSV60139622; called by muse, mutect2
- KMT2D | c.13748_13755del p.C4583* | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | catalogued as COSV56452628; called by mutect2, pindel, varscan2
- KMT2E | c.4540A>C p.T1514P | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV57575141; called by muse, mutect2, varscan2
- LEPR | c.1630A>G p.K544E | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.165); catalogued as COSV60757192; called by muse, mutect2, varscan2
- LETMD1 | c.274+1G>A p.X92_splice | Splice Site (SNP) | VAF 6/44 reads (14%) | catalogued as COSV50398013; called by muse, mutect2
- LPCAT1 | c.280G>T p.V94F | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV99359001; called by muse, mutect2
- LRRIQ1 | c.2207A>T p.Y736F | Missense Mutation (SNP) | VAF 81/366 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV67832592; called by muse, mutect2, varscan2
- MAGEC2 | c.1115C>T p.S372F | Missense Mutation (SNP) | VAF 43/66 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV55999855; called by muse, mutect2, varscan2
- MAGEE1 | c.1576C>T p.R526C | Missense Mutation (SNP) | VAF 24/29 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs782500356, COSV63910642; called by muse, mutect2, varscan2
- MAP3K1 | c.4064G>A p.R1355H | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as rs768719008, COSV68124465; called by muse, mutect2, varscan2
- MCOLN1 | c.721A>G p.N241D | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.41); catalogued as COSV51174009, COSV51176743; called by muse, mutect2, varscan2
- MFAP1 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.899); catalogued as COSV51039449; called by muse, mutect2, varscan2
- MIA2 | c.478C>A p.Q160K | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.65); catalogued as COSV54484151, COSV54485678; called by muse, mutect2, varscan2
- MINAR1 | c.2261C>T p.P754L | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100549012, COSV59583832; called by muse, mutect2, varscan2
- MRPS34 | c.428C>G p.P143R | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV51601223; called by muse, mutect2, varscan2
- MTMR6 | c.780C>G p.N260K | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs1430653449, COSV67808651; called by muse, mutect2, varscan2
- MUC16 | c.4855G>C p.E1619Q | Missense Mutation (SNP) | VAF 60/183 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.192); catalogued as COSV67468191, COSV67473903, COSV67497811; called by muse, mutect2, varscan2
- MXRA5 | c.2325C>G p.N775K | Missense Mutation (SNP) | VAF 48/79 reads (61%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV54239008; called by muse, varscan2
- NCOR1 | c.4504A>T p.T1502S | Missense Mutation (SNP) | VAF 40/203 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV51979566; called by muse, mutect2, varscan2
- NEDD4L | c.1957G>A p.E653K (on ENST00000400345 / NM_001144967.3; = p.E633K on NM_015277.6) | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.355); catalogued as COSV56846864; called by muse, mutect2, varscan2
- NEXMIF | c.3134C>G p.P1045R | Missense Mutation (SNP) | VAF 38/61 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50041409; called by muse, mutect2, varscan2
- NFAT5 | c.2406A>C p.L802F | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV63028604; called by muse, mutect2, varscan2
- NFIB | c.904A>G p.T302A | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.093); catalogued as COSV66626933; called by muse, mutect2, varscan2
- NOL6 | c.1579C>T p.H527Y | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.903); catalogued as rs760969123, COSV53042826, COSV99954468; called by muse, mutect2, varscan2
- NRTN | c.43A>G p.S15G | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.01); catalogued as COSV57468162; called by muse, mutect2, varscan2
- NTRK2 | c.629A>T p.E210V | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.943); catalogued as COSV52867565; called by muse, mutect2, varscan2
- NUP107 | c.1175G>C p.G392A | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as COSV57495445; called by muse, mutect2, varscan2
- NUP98 | c.525A>C p.K175N | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61433760; called by muse, mutect2, varscan2
- OR10J3 | c.985T>C p.Y329H | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.102); catalogued as COSV59954787; called by muse, mutect2, varscan2
- OR10V1 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as rs559488515, COSV100276309, COSV55698691; called by muse, mutect2, varscan2
- OR1J2 | c.158C>G p.S53C | Missense Mutation (SNP) | VAF 68/223 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.853); catalogued as rs1453347522, COSV58944537; called by muse, mutect2, varscan2
- OR2L3 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 51/187 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as rs765931236, COSV63455451; called by muse, mutect2, varscan2
- OR3A1 | c.947G>C p.*316Sext*5 | Nonstop Mutation (SNP) | VAF 14/71 reads (20%) | catalogued as COSV60163795; called by muse, mutect2, varscan2
- PACSIN1 | c.60G>C p.W20C | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55060759; called by muse, mutect2, varscan2
- PACSIN1 | c.61G>T p.E21* | Nonsense Mutation (SNP) | VAF 8/35 reads (23%) | catalogued as COSV99763082; called by muse, mutect2, varscan2
- PAK4 | c.46A>C p.N16H | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58945413; called by muse, mutect2, varscan2
- PANK4 | c.181G>C p.V61L | Missense Mutation (SNP) | VAF 46/189 reads (24%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.625); catalogued as COSV65867003; called by muse, varscan2
- PCDHA11 | c.1133C>G p.S378* | Nonsense Mutation (SNP) | VAF 18/90 reads (20%) | catalogued as COSV56481009; called by muse, mutect2, varscan2
- PCSK5 | c.74G>T p.C25F | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV65090789; called by muse, mutect2, varscan2
- PEG3 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 76/119 reads (64%) | SIFT tolerated (0.08); PolyPhen benign (0.321); catalogued as COSV55637186; called by muse, mutect2, varscan2
- PHF3 | c.2698G>C p.E900Q | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50322342; called by muse, mutect2, varscan2
- PLXNB2 | c.2964C>G p.F988L | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.67); PolyPhen benign (0.346); catalogued as rs202117989, COSV63782463; called by muse, mutect2
- POC1B-GALNT4 | c.1050G>T p.E350D | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1476144938, COSV57966146, COSV57969544; called by muse, mutect2, varscan2
- PTBP2 | c.382C>G p.H128D (on ENST00000426398 / NM_001300986.2; = p.H120D on NM_021190.4) | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.923); catalogued as COSV64624951; called by muse, mutect2, varscan2
- PTDSS1 | c.1223A>G p.H408R | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1044410031, COSV61265116; called by muse, mutect2, varscan2
- PTPRS | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV53623583; called by muse, mutect2, varscan2
- RAB8B | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as COSV58490100; called by muse, mutect2, varscan2
- RALGPS1 | c.980G>A p.G327D | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as COSV52224518; called by muse, mutect2, varscan2
- RAPGEF6 | c.2323G>A p.E775K | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV57248522; called by muse, mutect2, varscan2
- RB1 | c.2281A>C p.M761L | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.771); catalogued as COSV57306335, COSV57311986; called by muse, varscan2
- RHOB | c.223C>A p.P75T | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV55355269, COSV55355916; called by muse, mutect2, varscan2
- RPL36 | c.212A>C p.K71T | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56798817; called by muse, mutect2, varscan2
- RTTN | c.863C>T p.S288F | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.096); catalogued as COSV55346781; called by muse, mutect2, varscan2
- RYR1 | c.875T>A p.L292H | Missense Mutation (SNP) | VAF 22/310 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62100689; called by muse, mutect2
- SBNO1 | c.916G>A p.E306K (on ENST00000420886; = p.E305K on NM_018183.5) | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.657); catalogued as COSV57342611; called by muse, mutect2, varscan2
- SCAF4 | c.2656A>G p.M886V | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as COSV54256516; called by muse, mutect2, varscan2
- SDHA | c.1482G>A p.M494I | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV53769638; called by muse, mutect2, varscan2
- SEC31B | c.1322T>C p.L441S | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1442119194, COSV64824898; called by muse, mutect2, varscan2
- SECISBP2L | c.783G>C p.Q261H | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as COSV55935163; called by muse, mutect2, varscan2
- SELENOS | c.527G>A p.W176* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as rs780727815; called by muse, mutect2, varscan2
- SEMA3A | c.293C>A p.T98N | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.027); catalogued as COSV54874562; called by muse, mutect2, varscan2
- SEMA3D | c.2296A>G p.R766G | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV52396255; called by muse, mutect2, varscan2
- SEZ6L2 | c.461C>T p.T154M (on ENST00000308713 / NM_001114099.3; = p.T84M on NM_012410.4) | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs753073374, COSV58100506; called by muse, mutect2, varscan2
- SLC12A3 | c.2212C>G p.L738V | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as COSV52636042; called by muse, mutect2, varscan2
- SLF2 | c.506G>C p.R169P | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV53275025, COSV99488706; called by muse, mutect2, varscan2
- SLK | c.3266G>T p.S1089I | Missense Mutation (SNP) | VAF 49/153 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59826218; called by muse, mutect2, varscan2
- SLX4IP | c.148G>C p.D50H | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.647); catalogued as COSV57947791; called by muse, mutect2, varscan2
- SPTBN4 | c.3946G>A p.E1316K | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58952041; called by muse, mutect2, varscan2
- STAG2 | c.626_627del p.D209Vfs*29 | Frame Shift Del (DEL) | VAF 92/152 reads (61%) | catalogued as COSV54362127; called by pindel, varscan2
- STAT6 | c.161G>A p.S54N | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.1); catalogued as rs575257117, COSV55671840; called by muse, mutect2, varscan2
- STX10 | c.732C>G p.I244M | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV52834917; called by muse, mutect2, varscan2
- TAGLN3 | c.35G>A p.R12Q | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.284); catalogued as COSV56328422; called by muse, mutect2, varscan2
- TET2 | c.2966C>T p.P989L | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs937106410, COSV54416309; called by muse, mutect2, varscan2
- TFAP2A | c.974G>C p.R325P (on ENST00000482890; = p.R317P on NM_001032280.3) | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60234808; called by muse, mutect2, varscan2
- THOC5 | c.849T>A p.D283E | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63799265; called by muse, mutect2, varscan2
- TJP1 | c.3545G>T p.G1182V | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV62042965; called by muse, mutect2, varscan2
- TLK2 | c.1254G>C p.K418N (on ENST00000326270 / NM_001284333.2; = p.K396N on NM_006852.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/104 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.501); catalogued as COSV58301601; called by muse, mutect2, varscan2
- TLX3 | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51540625; called by muse, mutect2
- TMTC2 | c.1561T>C p.Y521H | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV58272482; called by muse, mutect2, varscan2
- TNFSF13B | c.7G>C p.D3H | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.443); catalogued as COSV65516436; called by muse, mutect2, varscan2
- TNKS2 | c.733C>G p.L245V | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65415850; called by muse, mutect2, varscan2
- TP53 | c.859G>T p.E287* | Nonsense Mutation (SNP) | VAF 23/44 reads (52%) | catalogued as CM044948, COSV52679410, COSV52730707, COSV52765316; called by muse, mutect2, varscan2
- TRAT1 | c.409G>T p.D137Y | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV55469175; called by muse, mutect2, varscan2
- TRIM16L | c.778T>A p.F260I | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV67459481; called by muse, mutect2, varscan2
- TTF1 | c.1475G>C p.G492A | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV57504943; called by muse, mutect2, varscan2
- TTLL11 | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 53/167 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs774508269, COSV58647707; called by muse, mutect2, varscan2
- TTN | c.25228G>A p.V8410I (on ENST00000591111; = p.V7483I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 104/187 reads (56%) | PolyPhen benign (0); catalogued as rs544958705, COSV59996011, COSV60134266; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UCHL1 | c.14C>G p.P5R | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs991106482, COSV52651995; called by muse, mutect2, varscan2
- USP40 | c.443C>G p.S148C | Missense Mutation (SNP) | VAF 42/78 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1392397004, COSV52480049, COSV52482662; called by muse, mutect2, varscan2
- VANGL1 | c.691C>T p.L231F | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59620875; called by muse, mutect2, varscan2
- VIRMA | c.3223G>A p.V1075I | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as COSV52586424; called by muse, mutect2, varscan2
- VPS35 | c.1442C>T p.P481L | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as COSV54479483; called by muse, mutect2, varscan2
- WDR6 | c.2044T>A p.Y682N | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.809); catalogued as COSV58245446; called by muse, mutect2, varscan2
- WRN | c.3016A>C p.T1006P | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.255); catalogued as COSV53301756; called by muse, mutect2, varscan2
- ZFAND5 | c.536G>C p.R179P | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52988262; called by muse, mutect2, varscan2
- ZNF276 | c.488G>C p.G163A (on ENST00000443381 / NM_001113525.2; = p.G88A on NM_152287.4) | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.044); catalogued as COSV57069492; called by muse, mutect2, varscan2
- ZNF654 | c.2469C>G p.N823K | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.062); catalogued as rs746078281, COSV58805470, COSV58806203; called by muse, mutect2, varscan2
- ZSCAN10 | c.1518G>C p.Q506H (on ENST00000252463; = p.Q561H on NM_032805.3) | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV52968658; called by muse, mutect2, varscan2
- ZXDC | c.915G>C p.E305D | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.47); catalogued as COSV60447341; called by muse, mutect2, varscan2
- ZZEF1 | c.5350G>A p.D1784N | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.385); catalogued as COSV67558189; called by muse, mutect2, varscan2
- CCZ1B | c.391-1G>T p.X131_splice | Splice Site (SNP) | VAF 5/44 reads (11%) | called by mutect2, varscan2
- DPPA3 | c.338G>A p.R113K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.9); PolyPhen benign (0.003); called by muse, mutect2
- EIF4A2 | c.541_544del p.V181Wfs*8 | Frame Shift Del (DEL) | VAF 38/78 reads (49%) | called by pindel, varscan2
- EPB41L3 | c.2197_2201del p.T733Hfs*2 | Frame Shift Del (DEL) | VAF 30/124 reads (24%) | called by mutect2, pindel, varscan2
- FARP1 | c.376C>T p.Q126* | Nonsense Mutation (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2, varscan2
- FLNC | c.3262A>T p.K1088* | Nonsense Mutation (SNP) | VAF 20/74 reads (27%) | called by muse, mutect2, varscan2
- GGT7 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.369); called by muse, mutect2
- LMTK3 | c.136T>C p.C46R | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LRP10 | c.1831G>T p.E611* | Nonsense Mutation (SNP) | VAF 20/79 reads (25%) | called by muse, mutect2, varscan2
- MARK2 | c.274_276del p.S93del | In Frame Del (DEL) | VAF 22/175 reads (13%) | called by pindel, varscan2
- MAT1A | c.564C>A p.Y188* | Nonsense Mutation (SNP) | VAF 48/160 reads (30%) | called by muse, mutect2, varscan2
- MEX3A | c.438G>C p.E146D | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MTHFD2 | c.163_169del p.Q55* | Frame Shift Del (DEL) | VAF 30/73 reads (41%) | called by mutect2, pindel, varscan2
- NMRAL1 | c.868G>T p.E290* | Nonsense Mutation (SNP) | VAF 47/130 reads (36%) | called by muse, mutect2, varscan2
- RB1 | c.2231_2240del p.I744Rfs*7 | Frame Shift Del (DEL) | VAF 10/45 reads (22%) | called by pindel, varscan2
- RESF1 | c.4148_4149dup p.D1384* | Frame Shift Ins (INS) | VAF 10/75 reads (13%) | called by mutect2, pindel, varscan2
- RUSC1 | c.1183G>A p.A395T | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); called by muse, varscan2
- SEC24C | c.2381_2405del p.K794Rfs*28 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | called by mutect2, pindel
- SNCAIP | c.1936C>T p.Q646* | Nonsense Mutation (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- TBC1D32 | c.1808C>G p.S603* | Nonsense Mutation (SNP) | VAF 19/53 reads (36%) | called by muse, mutect2
- USP9X | c.4685C>T p.A1562V | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ZNF750 | c.1289dup p.Y431Vfs*29 | Frame Shift Ins (INS) | VAF 20/108 reads (19%) | called by mutect2, pindel, varscan2
- AGPAT1 | c.486C>T p.V162= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as rs141411867, COSV61247938; called by muse, mutect2, varscan2
- ALDH16A1 | c.2010C>T p.D670= | Silent (SNP) | VAF 119/202 reads (59%) | catalogued as rs781582861, COSV53194695; called by muse, mutect2, varscan2
- ANKRD20A4P | c.1923T>C p.S641= | Silent (SNP) | VAF 42/384 reads (11%) | catalogued as rs111880971; called by muse, mutect2, varscan2
- ARID1A | c.3082C>T p.L1028= | Silent (SNP) | VAF 54/162 reads (33%) | catalogued as COSV61380134; called by muse, mutect2, varscan2
- ATM | c.1668A>G p.K556= | Silent (SNP) | VAF 54/122 reads (44%) | catalogued as COSV53750853; called by muse, mutect2, varscan2
- BAZ1B | c.2769C>T p.F923= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as COSV59991935; called by muse, varscan2
- BTN3A2 | c.276G>A p.P92= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as rs777440212, COSV100709641, COSV62688118; called by mutect2, varscan2
- C19orf25 | c.240C>A p.G80= | Silent (SNP) | VAF 7/12 reads (58%) | called by muse, mutect2, varscan2
- C19orf57 | c.1446G>C p.V482= | Silent (SNP) | VAF 27/101 reads (27%) | catalogued as COSV60968787; called by muse, mutect2, varscan2
- CACNG8 | c.423C>G p.L141= | Silent (SNP) | VAF 20/28 reads (71%) | catalogued as COSV54414917, COSV54415281; called by muse, mutect2, varscan2
- DDX46 | c.2049A>C p.L683= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as COSV62799669; called by muse, mutect2, varscan2
- DOP1A | c.4836T>A p.S1612= | Silent (SNP) | VAF 32/80 reads (40%) | catalogued as COSV52712002; called by muse, mutect2, varscan2
- DPY19L3 | c.612A>G p.R204= | Silent (SNP) | VAF 58/155 reads (37%) | catalogued as rs1209694969, COSV60477670; called by muse, mutect2, varscan2
- ENO1 | c.315G>A p.K105= | Silent (SNP) | VAF 37/125 reads (30%) | catalogued as COSV52304269; called by muse, mutect2, varscan2
- FBXL8 | c.981C>T p.C327= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs1320058764; called by muse, mutect2, varscan2
- FCN1 | c.375G>A p.G125= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs776937248, COSV65662548; called by muse, mutect2, varscan2
- GP1BA | c.1614C>T p.L538= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as rs748793531, COSV56699450; called by muse, mutect2, varscan2
- GPR68 | c.435C>T p.I145= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV53176353, COSV53176638; called by muse, mutect2, varscan2
- HMCN1 | c.6730C>A p.R2244= | Silent (SNP) | VAF 17/120 reads (14%) | catalogued as COSV54909354; called by muse, mutect2, varscan2
- HSPA8 | c.1896C>T p.P632= | Silent (SNP) | VAF 15/95 reads (16%) | catalogued as rs763753426, COSV57084357; called by muse, mutect2, varscan2
- KIF14 | c.2247A>T p.T749= | Silent (SNP) | VAF 67/377 reads (18%) | catalogued as rs1000782693, COSV66262231; called by muse, mutect2, varscan2
- KIF1A | c.4437C>T p.H1479= (on ENST00000320389 / NM_001379639.1; = p.H1471= on NM_004321.8 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs375640417; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KLHL14 | c.381G>A p.L127= | Silent (SNP) | VAF 46/171 reads (27%) | catalogued as COSV63833438; called by muse, mutect2, varscan2
- KRT7 | c.1362T>G p.A454= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as COSV57766536; called by muse, mutect2, varscan2
- LRP1 | c.2208G>T p.V736= | Silent (SNP) | VAF 35/127 reads (28%) | catalogued as COSV54514918; called by muse, mutect2, varscan2
- MARK4 | c.387G>A p.K129= | Silent (SNP) | VAF 94/148 reads (64%) | catalogued as COSV53465060; called by muse, mutect2, varscan2
- NPY2R | c.939C>T p.I313= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as rs762985604, COSV61528638; called by muse, mutect2, varscan2
- OR10A5 | c.42C>T p.L14= | Silent (SNP) | VAF 100/237 reads (42%) | catalogued as COSV55054646; called by muse, mutect2, varscan2
- PARP14 | c.60G>T p.P20= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV72111726; called by muse, mutect2, varscan2
- PCBP3 | c.540C>T p.I180= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as rs745416248, COSV68408499; called by muse, mutect2, varscan2
- PDZD8 | c.2853C>G p.V951= | Silent (SNP) | VAF 83/314 reads (26%) | catalogued as rs746129778, COSV53691291; called by muse, mutect2, varscan2
- PHF24 | c.261C>T p.G87= | Silent (SNP) | VAF 56/172 reads (33%) | catalogued as rs780311819, COSV54273146; called by muse, mutect2, varscan2
- POU2F1 | c.201T>G p.S67= (on ENST00000541643 / NM_001365848.1; = p.S90= on NM_002697.4) | Silent (SNP) | VAF 31/173 reads (18%) | catalogued as COSV54818841; called by muse, mutect2, varscan2
- PPP1R13L | c.1464C>T p.L488= | Silent (SNP) | VAF 30/58 reads (52%) | catalogued as COSV62908768; called by muse, mutect2, varscan2
- PREX1 | c.4458G>C p.A1486= | Silent (SNP) | VAF 53/191 reads (28%) | catalogued as COSV64253115; called by muse, mutect2, varscan2
- PRKCA | c.36G>A p.A12= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs757577723; called by muse, mutect2, varscan2
- PRKD1 | c.1698A>G p.V566= | Silent (SNP) | VAF 27/94 reads (29%) | catalogued as COSV59573189; called by muse, mutect2, varscan2
- RYR1 | c.876C>A p.L292= | Silent (SNP) | VAF 22/314 reads (7%) | catalogued as COSV62100695; called by muse, mutect2
- SAMD9 | c.3306T>C p.A1102= | Silent (SNP) | VAF 36/152 reads (24%) | catalogued as COSV66076122; called by muse, mutect2, varscan2
- SELE | c.1563T>G p.P521= | Silent (SNP) | VAF 56/112 reads (50%) | catalogued as COSV60976302; called by muse, mutect2, varscan2
- SLC12A6 | c.105C>T p.L35= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as rs766024839, COSV62544806; called by muse, mutect2, varscan2
- SLC23A2 | c.951C>T p.I317= | Silent (SNP) | VAF 30/137 reads (22%) | catalogued as COSV57775590; called by muse, mutect2, varscan2
- SLC36A3 | c.993G>A p.K331= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as COSV58857216; called by muse, mutect2
- SLITRK4 | c.595C>T p.L199= | Silent (SNP) | VAF 48/86 reads (56%) | catalogued as COSV62023171; called by muse, mutect2, varscan2
- SPANXB1 | c.162G>A p.S54= | Silent (SNP) | VAF 72/588 reads (12%) | called by muse, varscan2
- TENT4A | c.1797C>T p.S599= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as COSV50096397; called by muse, mutect2, varscan2
- TGFBR3 | c.1806C>T p.L602= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV53026875; called by muse, mutect2, varscan2
- TMEM164 | c.792C>A p.T264= (on ENST00000372068 / NM_032227.4; = p.T115= on NM_017698.2) | Silent (SNP) | VAF 47/78 reads (60%) | catalogued as COSV55813135; called by muse, mutect2, varscan2
- TOP3A | c.2331C>T p.N777= | Silent (SNP) | VAF 22/123 reads (18%) | catalogued as rs1295546718, COSV58178459; called by muse, mutect2, varscan2
- VPS13C | c.9324C>T p.S3108= (on ENST00000644861 / NM_020821.3; = p.S3065= on NM_017684.5) | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as rs113570828, COSV51259184; called by muse, mutect2, varscan2
- VPS37B | c.132C>T p.N44= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as rs1278634899, COSV57360731; called by muse, mutect2, varscan2
- XIAP | c.1440G>A p.K480= | Silent (SNP) | VAF 42/66 reads (64%) | catalogued as rs61757634, COSV63022658; called by muse, mutect2, varscan2
- ZAP70 | c.540G>A p.G180= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV53855004; called by muse, mutect2, varscan2
- ZC3H14 | c.1680C>G p.L560= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV51770704; called by muse, mutect2, varscan2
- ZC3HC1 | c.1167C>G p.G389= | Silent (SNP) | VAF 25/130 reads (19%) | catalogued as COSV61298790; called by muse, mutect2, varscan2
- GABRG2 | c.1249-667T>A | Intron (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- GLS | c.1650+1161A>C | Intron (SNP) | VAF 14/33 reads (42%) | catalogued as COSV57842955; called by muse, mutect2, varscan2
- JTB | c.-2C>T | 5'UTR (SNP) | VAF 18/72 reads (25%) | catalogued as rs767096034, COSV99665713; called by muse, mutect2
- MASP1 | c.1303+5583A>T | Intron (SNP) | VAF 23/81 reads (28%) | catalogued as COSV56224575; called by muse, mutect2, varscan2
- METTL16 | n.1044G>C | RNA (SNP) | VAF 16/33 reads (48%) | called by muse, mutect2, varscan2
- SH3GL3 | c.45+43267C>G | Intron (SNP) | VAF 50/145 reads (34%) | catalogued as COSV100197400, COSV61057998; called by muse, mutect2, varscan2
